Somatic mutation profile of cancer-model specimen HCM-CSHL-0089-C25-85M (3D Organoid; aliquot HCM-CSHL-0089-C25-85M-01D-A78T-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0089-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 62.5 years (22,825 days).
Specimen HCM-CSHL-0089-C25-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0a61d41a-c6f4-4d94-a4e5-318d186f3221.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0089-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0089-C25-10A-01D-A77E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a5932f1-0205-432a-a315-e77f01c82252

The open-access MAF lists 86 somatic variants for this specimen: 63 protein-altering or splice-affecting, 13 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 13, Frame Shift Del 6, Intron 5, Frame Shift Ins 5, RNA 2, 5'UTR 2, Nonsense Mutation 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 700/701 reads (100%) | hotspot (GDC flag); catalogued as rs121913387, CM940227, COSV58682666, COSV58721549, COSV99053472; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 201/432 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TG | c.7007G>A p.R2336Q | Missense Mutation (SNP) | VAF 289/883 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912650, CM063181, COSV55069861; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.584T>C p.I195T | Missense Mutation (SNP) | VAF 327/329 reads (99%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs760043106, CM092575, COSV52661172, COSV52664264, COSV52684176, COSV52720899; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS2 | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 311/578 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs763733632; called by muse, mutect2, varscan2
- ADAMTS4 | c.2119G>T p.A707S | Missense Mutation (SNP) | VAF 82/146 reads (56%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV63491126; called by muse, mutect2
- AKAP6 | c.2428G>A p.A810T | Missense Mutation (SNP) | VAF 40/502 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55213214; called by muse, mutect2
- ARID3A | c.1507C>T p.R503C | Missense Mutation (SNP) | VAF 166/339 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs781106095, COSV55046653; called by muse, mutect2, varscan2
- CCKBR | c.1193G>A p.R398H | Missense Mutation (SNP) | VAF 89/407 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs897640161, COSV58098875; called by muse, mutect2, varscan2
- COL6A6 | c.2708G>A p.R903Q | Missense Mutation (SNP) | VAF 48/167 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1313232339, COSV62024644; called by muse, mutect2, varscan2
- CYP4F11 | c.572T>A p.M191K | Missense Mutation (SNP) | VAF 208/456 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs1461992996; called by muse, mutect2, varscan2
- DLGAP2 | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 163/354 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.12); catalogued as rs1309261843; called by muse, mutect2, varscan2
- EIF2AK1 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1384063838, COSV52240872; called by muse, mutect2, varscan2
- ENDOD1 | c.549C>G p.D183E | Missense Mutation (SNP) | VAF 81/269 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV53589112; called by muse, mutect2, varscan2
- FAM216B | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 66/127 reads (52%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.943); catalogued as COSV58270150; called by muse, mutect2, varscan2
- JAK3 | c.2519G>A p.R840H | Missense Mutation (SNP) | VAF 318/688 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.58); catalogued as rs140837014; called by muse, varscan2
- KMT2D | c.13895del p.P4632Hfs*8 | Frame Shift Del (DEL) | VAF 110/288 reads (38%) | catalogued as CD114933; called by mutect2, pindel, varscan2
- MYOZ3 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 158/341 reads (46%) | SIFT tolerated (0.91); PolyPhen benign (0.006); catalogued as rs766224195, COSV51739562; called by muse, mutect2, varscan2
- OGDHL | c.1052G>A p.R351Q | Missense Mutation (SNP) | VAF 121/204 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as rs767864251, COSV65100729; called by muse, mutect2, varscan2
- OR13G1 | c.543G>T p.L181F | Missense Mutation (SNP) | VAF 116/225 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV62943607; called by muse, mutect2, varscan2
- PEG10 | c.767C>T p.A256V (on ENST00000482108 / NM_001040152.2; = p.A290V on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/354 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.502); catalogued as COSV71788230; called by muse, mutect2
- PSMA1 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 55/137 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.242); catalogued as rs770318291; called by muse, mutect2, varscan2
- PTPRD | c.5188C>T p.R1730W | Missense Mutation (SNP) | VAF 84/171 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775122610, COSV61982613; called by muse, mutect2, varscan2
- RUNX1T1 | c.1219G>A p.G407S (on ENST00000265814 / NM_001198628.1; = p.G380S on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 308/616 reads (50%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs202121288; called by muse, mutect2, varscan2
- SMAD4 | c.1217C>T p.A406V | Missense Mutation (SNP) | VAF 208/209 reads (100%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.993); catalogued as rs1064796102, COSV61685043, COSV61685722; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SULT4A1 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 250/363 reads (69%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV50782227; called by muse, mutect2, varscan2
- THBS2 | c.1922C>T p.T641M | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.532); catalogued as rs1451706316, COSV64679569; called by muse, mutect2, varscan2
- TPO | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 89/300 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1210957618; ClinVar: uncertain significance; called by mutect2, varscan2
- TUBB8B | c.37G>A p.G13R | Missense Mutation (SNP) | VAF 20/232 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.891); catalogued as rs1438106680; called by muse, mutect2
- UNC5B | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 105/400 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as rs1157473537, COSV58975273, COSV58975519; called by muse, mutect2, varscan2
- VAV1 | c.676C>T p.R226W | Missense Mutation (SNP) | VAF 177/392 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.954); catalogued as rs774426463; called by muse, mutect2, varscan2
- WDFY4 | c.7981G>A p.G2661R | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1020451728; called by muse, mutect2
- ZDBF2 | c.563C>A p.A188D | Missense Mutation (SNP) | VAF 120/196 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.605); catalogued as COSV65622248; called by muse, mutect2, varscan2
- ZNF569 | c.389dup p.S132Ffs*7 | Frame Shift Ins (INS) | VAF 44/144 reads (31%) | catalogued as rs752923644; called by mutect2, pindel, varscan2
- ACSL5 | c.1871A>G p.Q624R (on ENST00000354273; = p.Q680R on NM_016234.3) | Missense Mutation (SNP) | VAF 132/214 reads (62%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ACVR2A | c.1309_1310del p.K437Efs*19 | Frame Shift Del (DEL) | VAF 90/212 reads (42%) | called by pindel, varscan2
- AMOT | c.1756G>A p.V586M (on ENST00000371959 / NM_001113490.1; = p.V177M on NM_133265.3) | Missense Mutation (SNP) | VAF 69/159 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ARMCX3 | c.654dup p.S219Ifs*17 | Frame Shift Ins (INS) | VAF 20/21 reads (95%) | called by mutect2, varscan2
- CIC | c.3727_3728insT p.A1243Vfs*12 | Frame Shift Ins (INS) | VAF 147/365 reads (40%) | called by mutect2, pindel, varscan2
- CLNK | c.533dup p.E179* | Frame Shift Ins (INS) | VAF 61/160 reads (38%) | called by mutect2, pindel, varscan2
- CNBD1 | c.493G>T p.D165Y | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- EMILIN3 | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 14/278 reads (5%) | SIFT tolerated (0.56); PolyPhen benign (0.015); called by muse, mutect2
- EPM2AIP1 | c.1055T>G p.F352C | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EXOC5 | c.637A>T p.R213* | Nonsense Mutation (SNP) | VAF 56/229 reads (24%) | called by muse, mutect2, varscan2
- FANCG | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 366/750 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FBXO33 | c.1131_1139delinsG p.F377Lfs*3 | Frame Shift Del (DEL) | VAF 61/312 reads (20%) | called by pindel, varscan2*
- GNAT3 | c.107T>A p.L36Q | Missense Mutation (SNP) | VAF 177/328 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GUCY1A1 | c.1402C>A p.Q468K | Missense Mutation (SNP) | VAF 123/564 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- HAVCR1 | c.476C>A p.T159K | Missense Mutation (SNP) | VAF 326/660 reads (49%) | SIFT tolerated (0.36); PolyPhen benign (0.063); called by mutect2, varscan2
- HOMER2 | c.442_445dup p.D149Gfs*3 (on ENST00000304231 / NM_199330.3; = p.D138Gfs*3 on NM_004839.4) | Frame Shift Ins (INS) | VAF 105/297 reads (35%) | called by mutect2, varscan2
- IFNK | c.140A>C p.H47P | Missense Mutation (SNP) | VAF 20/394 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.017); called by muse, mutect2
- ITGB6 | c.2029_2039del p.E677Yfs*8 | Frame Shift Del (DEL) | VAF 34/175 reads (19%) | called by mutect2, pindel, varscan2
- KLK6 | c.361C>A p.L121I | Missense Mutation (SNP) | VAF 231/482 reads (48%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NEXMIF | c.3808T>A p.S1270T | Missense Mutation (SNP) | VAF 177/177 reads (100%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PCBP3 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- PPP1R15B | c.566G>A p.S189N | Missense Mutation (SNP) | VAF 102/193 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- PRPF40A | c.263G>T p.R88L | Missense Mutation (SNP) | VAF 249/385 reads (65%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- PXMP2 | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 271/567 reads (48%) | SIFT tolerated (0.4); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SGSM1 | c.767T>C p.L256P | Missense Mutation (SNP) | VAF 19/509 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2
- SLC41A3 | c.302del p.D101Afs*3 | Frame Shift Del (DEL) | VAF 29/94 reads (31%) | called by mutect2, pindel, varscan2
- THSD7B | c.3639C>A p.S1213R (on ENST00000272643; = p.S1211R on NM_001316349.2) | Missense Mutation (SNP) | VAF 64/237 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- TMEM94 | c.2605del p.M869Wfs*39 | Frame Shift Del (DEL) | VAF 94/189 reads (50%) | called by mutect2, pindel, varscan2
- ZNF396 | c.338A>C p.Q113P | Missense Mutation (SNP) | VAF 173/275 reads (63%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- ATP13A5 | c.1260T>C p.Y420= | Silent (SNP) | VAF 55/142 reads (39%) | called by muse, mutect2, varscan2
- CHD6 | c.6708C>T p.S2236= | Silent (SNP) | VAF 299/569 reads (53%) | catalogued as rs951814095; called by muse, mutect2, varscan2
- ELFN2 | c.57C>T p.A19= | Silent (SNP) | VAF 181/271 reads (67%) | catalogued as rs756407312; called by muse, mutect2, varscan2
- HUNK | c.570G>A p.E190= | Silent (SNP) | VAF 52/106 reads (49%) | catalogued as COSV54227106; called by muse, mutect2, varscan2
- MATN4 | c.207C>T p.N69= | Silent (SNP) | VAF 78/178 reads (44%) | catalogued as COSV59212971; called by muse, mutect2, varscan2
- NAT1 | c.279T>G p.V93= | Silent (SNP) | VAF 144/321 reads (45%) | called by muse, mutect2, varscan2
- OR2T6 | c.138C>T p.I46= | Silent (SNP) | VAF 51/109 reads (47%) | called by muse, mutect2, varscan2
- PCDH9 | c.2457C>A p.I819= | Silent (SNP) | VAF 104/326 reads (32%) | called by muse, mutect2, varscan2
- PHTF1 | c.2259T>C p.F753= | Silent (SNP) | VAF 41/165 reads (25%) | called by muse, mutect2, varscan2
- PPP2R1A | c.1182G>T p.V394= | Silent (SNP) | VAF 170/324 reads (52%) | called by muse, mutect2, varscan2
- SKOR1 | c.876C>T p.G292= | Silent (SNP) | VAF 133/214 reads (62%) | catalogued as rs746508508; called by muse, mutect2, varscan2
- VPS13B | c.3843A>C p.P1281= | Silent (SNP) | VAF 101/423 reads (24%) | catalogued as rs766922292; called by muse, mutect2, varscan2
- ZBTB20 | c.420C>T p.I140= (on ENST00000474710 / NM_001164342.2; = p.I67= on NM_015642.6 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 147/439 reads (33%) | catalogued as COSV61847669; called by muse, mutect2, varscan2
- ARHGEF19 | c.1138-94C>G | Intron (SNP) | VAF 40/130 reads (31%) | called by muse, varscan2
- ARHGEF4 | chr2:130916414 G>A | 5'Flank (SNP) | VAF 46/160 reads (29%) | called by muse, mutect2, varscan2
- DRGX | c.-23T>A | 5'UTR (SNP) | VAF 111/303 reads (37%) | called by muse, mutect2, varscan2
- KCNU1 | c.2010-17035G>A | Intron (SNP) | VAF 198/366 reads (54%) | catalogued as rs769673898; called by muse, mutect2, varscan2
- MYLK | c.3652+49C>T | Intron (SNP) | VAF 90/285 reads (32%) | called by muse, mutect2, varscan2
- PDCD6 | c.-48G>A | 5'UTR (SNP) | VAF 137/635 reads (22%) | catalogued as rs752212065; called by muse, mutect2, varscan2
- RPL27A | c.68-97T>G | Intron (SNP) | VAF 12/173 reads (7%) | called by muse, mutect2
- TPI1 | c.227-459T>A | Intron (SNP) | VAF 142/293 reads (48%) | called by muse, varscan2
- TUBB7P | n.37G>A | RNA (SNP) | VAF 36/173 reads (21%) | catalogued as rs782640561; called by muse, varscan2
- ZNF733P | n.628T>A | RNA (SNP) | VAF 42/386 reads (11%) | called by muse, varscan2
